Somatic mutation profile of tumor specimen C3N-02971-01 (aliquot CPT0185920007) from CPTAC case C3N-02971, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 78.4 years (28,635 days).
Specimen C3N-02971-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0025c83d-3ed9-499b-8a28-c8af1dcf26b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02971-31 (Blood Derived Normal), aliquot CPT0187270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb5d7f2-1e72-4ba4-84d6-9392c5c0a320

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 12, Intron 3, RNA 2, 5'Flank 2, Splice Region 2, Nonsense Mutation 1, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 64/535 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 184/697 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C16orf96 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 38/471 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs759379003; called by muse, mutect2
- CCDC40 | c.2192A>G p.N731S | Missense Mutation (SNP) | VAF 49/781 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs376612893; called by muse, mutect2
- CCL11 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs56120942; called by muse, mutect2, varscan2
- CEP250 | c.3988C>T p.R1330W | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs773111712; ClinVar: uncertain significance; called by muse, mutect2
- GABRG3 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV61529562; called by muse, mutect2
- HEPACAM | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.594); catalogued as rs571879332, COSV100005628, COSV100005724; called by muse, mutect2
- IMPG1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 52/884 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs769499134, COSV64059410; called by muse, mutect2
- KANSL1 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 96/1180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99295031; called by muse, mutect2
- LRFN1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50434815; called by muse, mutect2, varscan2
- LY6H | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1221103879; called by muse, mutect2
- LZTS1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 93/514 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs376917114; called by muse, mutect2, varscan2
- MLLT10 | c.2061A>C p.P687= (on ENST00000307729 / NM_001195626.3; = p.P703= on NM_004641.3) | Splice Region (SNP) | VAF 33/391 reads (8%) | catalogued as rs745498825; called by muse, mutect2
- MOG | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749783831; called by muse, mutect2, varscan2
- MYH10 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs752480302; called by muse, mutect2, varscan2
- OR10R2 | c.521T>G p.L174W | Missense Mutation (SNP) | VAF 25/495 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV63769419; called by muse, mutect2
- OR2L8 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 56/561 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs565612069, COSV100594400, COSV61727112; called by muse, mutect2, varscan2
- P2RX1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 119/703 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1364204258; called by muse, mutect2, varscan2
- RHOBTB3 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs374462478, COSV101183159; called by muse, mutect2
- RUNX1T1 | c.1565C>T p.A522V (on ENST00000265814 / NM_001198628.1; = p.A495V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56143042; called by muse, mutect2
- SEMA5A | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 37/759 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs377224069, COSV101228556; called by muse, mutect2
- SHCBP1 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 96/462 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.976); catalogued as rs759988033; called by muse, mutect2, varscan2
- SLC4A5 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 56/670 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1553452434, COSV61030120; called by muse, mutect2
- SPOPL | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs770111475; called by muse, mutect2, varscan2
- ST6GAL2 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 37/288 reads (13%) | PolyPhen possibly damaging (0.78); catalogued as COSV62416335; called by muse, mutect2, varscan2
- TLE2 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs1178870460; called by muse, mutect2, varscan2
- TLL1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99288636; called by muse, mutect2
- ZNF75D | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 35/583 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781912304, COSV66133646; called by muse, mutect2
- ANKIB1 | c.2783A>C p.E928A | Missense Mutation (SNP) | VAF 244/672 reads (36%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 87/524 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CUX2 | c.4320C>A p.D1440E | Missense Mutation (SNP) | VAF 24/473 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- DENND4A | c.4612G>A p.D1538N | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- DPY19L1 | c.546-1G>A p.X182_splice | Splice Site (SNP) | VAF 48/299 reads (16%) | called by muse, mutect2, varscan2
- DST | c.6362T>G p.V2121G | Missense Mutation (SNP) | VAF 59/453 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- EPS8L3 | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 45/535 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- ERP44 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MN1 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPL35 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- P3H3 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2
- PIEZO1 | c.7231T>C p.C2411R | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2
- PIGR | c.1227C>A p.Y409* | Nonsense Mutation (SNP) | VAF 88/683 reads (13%) | called by muse, mutect2, varscan2
- RARS2 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 77/609 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDF1 | c.1601C>G p.A534G | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- RNASET2 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 85/754 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC16A4 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- SLC18A3 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 46/756 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SLC4A1 | c.16-7C>T | Splice Region (SNP) | VAF 52/620 reads (8%) | called by muse, mutect2
- SLCO1B1 | c.603A>T p.K201N | Missense Mutation (SNP) | VAF 24/369 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2
- SNRPA | c.507G>C p.M169I | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CLIC3 | c.231G>A p.Q77= | Silent (SNP) | VAF 32/292 reads (11%) | called by muse, mutect2, varscan2
- DHX9 | c.735A>G p.S245= | Silent (SNP) | VAF 41/388 reads (11%) | called by muse, mutect2, varscan2
- DUSP26 | c.327G>T p.L109= | Silent (SNP) | VAF 64/898 reads (7%) | called by muse, mutect2
- EGFR | c.2925C>T p.P975= | Silent (SNP) | VAF 109/950 reads (11%) | called by muse, mutect2, varscan2
- FLG | c.9957G>A p.P3319= | Silent (SNP) | VAF 135/919 reads (15%) | catalogued as rs774241945, COSV64242888; called by muse, mutect2, varscan2
- GABRB3 | c.1056C>T p.D352= | Silent (SNP) | VAF 47/601 reads (8%) | called by muse, mutect2
- GABRQ | c.618C>T p.Y206= | Silent (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- LMTK3 | c.2682C>T p.P894= | Silent (SNP) | VAF 105/689 reads (15%) | catalogued as rs747292842, COSV99539893; called by muse, mutect2, varscan2
- OR5K2 | c.69G>A p.L23= | Silent (SNP) | VAF 20/335 reads (6%) | called by muse, mutect2
- P4HA2 | c.1575C>T p.F525= | Silent (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- PCDHGB5 | c.1656C>T p.N552= | Silent (SNP) | VAF 109/843 reads (13%) | catalogued as COSV53956513; called by muse, mutect2, varscan2
- VWF | c.1896C>T p.A632= | Silent (SNP) | VAF 62/406 reads (15%) | called by muse, varscan2
- AC245047.1 | n.146C>T | RNA (SNP) | VAF 34/364 reads (9%) | catalogued as rs566338095; called by muse, mutect2
- DCHS2 | n.8001C>T | RNA (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- HDAC6 | chrX:48801902 A>T | 5'Flank (SNP) | VAF 50/497 reads (10%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.3426+32G>A | Intron (SNP) | VAF 38/435 reads (9%) | called by muse, mutect2
- POLR1G | c.-46T>A | 5'UTR (SNP) | VAF 42/474 reads (9%) | called by muse, mutect2
- RAD21 | chr8:116875493 G>T | 5'Flank (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2
- SERPINA7 | c.*13C>T | 3'UTR (SNP) | VAF 63/449 reads (14%) | catalogued as rs540469929; called by muse, mutect2, varscan2
- STIM2 | c.1764-1502G>A | Intron (SNP) | VAF 17/262 reads (6%) | catalogued as rs750475852; called by muse, mutect2
- TMPRSS11F | c.1015+2109T>G | Intron (SNP) | VAF 52/606 reads (9%) | catalogued as COSV100678845; called by muse, mutect2
